Somatic mutation profile of tumor specimen MMRF_1972_1_BM_CD138pos (aliquot MMRF_1972_1_BM_CD138pos_T1_KBS5U_L07264) from MMRF case MMRF_1972, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.1 years (29,977 days).
Specimen MMRF_1972_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9be691df-45ff-40ac-a462-91c44ba528da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1972_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1972_1_PB_Whole_C3_KBS5U_L07265; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b95a2f2-dc9a-4849-9cfb-a92cd71cc26c

The open-access MAF lists 152 somatic variants for this specimen: 67 protein-altering or splice-affecting, 22 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, 3'UTR 31, Silent 22, Intron 20, 5'UTR 7, Nonsense Mutation 6, RNA 2, Frame Shift Del 2, Splice Site 2, 5'Flank 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 69/212 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANLN | c.3362T>C p.I1121T | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1218381226; called by muse, mutect2, varscan2
- ATM | c.3077+2T>C p.X1026_splice | Splice Site (SNP) | VAF 57/235 reads (24%) | catalogued as COSV53781228; called by muse, mutect2, varscan2
- BNC2 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs565251984, COSV66142337; called by muse, mutect2, varscan2
- BRWD3 | c.4762G>A p.E1588K | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100956000; called by muse, mutect2
- CARD10 | c.1712C>A p.S571Y | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV99324850; called by muse, mutect2, varscan2
- CD46 | c.1022G>A p.S341N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1297426841; called by muse, mutect2, varscan2
- DLL1 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 40/203 reads (20%) | catalogued as COSV64538959; called by muse, mutect2, varscan2
- EHD1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs761533385, COSV100277209; called by muse, varscan2
- F2 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as rs200934494; called by muse, mutect2, varscan2
- IGHD2-2 | c.17A>G p.Y6C | Missense Mutation (SNP) | VAF 16/20 reads (80%) | catalogued as rs535073705; called by muse, mutect2, varscan2
- IGHV2-70 | c.228T>G p.D76E | Missense Mutation (SNP) | VAF 58/73 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs373802343; called by muse, varscan2
- MAB21L3 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 89/102 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs761323415, COSV65673750; called by muse, mutect2, varscan2
- MICAL3 | c.3493G>T p.A1165S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); catalogued as rs779450964; called by muse, mutect2, varscan2
- NOD2 | c.2572G>A p.G858S | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.222); catalogued as rs760938311, COSV56053693; called by muse, mutect2, varscan2
- PCSK5 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.023); catalogued as rs200049619, COSV65085478; called by muse, mutect2, varscan2
- PDZRN3 | c.1478A>T p.N493I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.552); catalogued as COSV55202526; called by muse, mutect2, varscan2
- POLR3B | c.10del p.L4* | Frame Shift Del (DEL) | VAF 18/36 reads (50%) | catalogued as COSV57278737; called by mutect2, pindel, varscan2
- PRLHR | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53305010; called by muse, mutect2, varscan2
- PTCHD1 | c.2173G>A p.V725I | Missense Mutation (SNP) | VAF 72/76 reads (95%) | SIFT tolerated (0.58); PolyPhen benign (0.104); catalogued as rs753840664; called by muse, mutect2, varscan2
- RASD2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs770684908, COSV53353440, COSV99332763; called by muse, mutect2, varscan2
- SPAG17 | c.4529G>A p.C1510Y | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770774268; called by muse, mutect2, varscan2
- TLL1 | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.501); catalogued as COSV50310750; called by muse, mutect2, varscan2
- TOX3 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54869325; called by muse, mutect2, varscan2
- TSPOAP1 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs766215697, COSV99272490; called by muse, mutect2, varscan2
- ZFHX4 | c.5854G>A p.G1952S | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs1248614594; called by muse, mutect2
- ZIC4 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101268196; called by muse, mutect2, varscan2
- ZNF132 | c.1759A>G p.I587V | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.041); catalogued as rs1028134336; called by muse, mutect2, varscan2
- ZNF541 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as rs751201378; called by muse, mutect2, varscan2
- ADGRG6 | c.3056T>C p.V1019A | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- ARGLU1 | c.589A>T p.K197* | Nonsense Mutation (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- AUTS2 | c.188del p.P63Rfs*31 | Frame Shift Del (DEL) | VAF 42/142 reads (30%) | called by mutect2, pindel, varscan2
- AZGP1 | c.494A>T p.K165M | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRWD1 | c.169A>G p.N57D | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- BTBD10 | c.877A>C p.I293L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C9orf64 | c.338-9_351del p.X113_splice | Splice Site (DEL) | VAF 95/481 reads (20%) | called by mutect2, pindel, varscan2
- CAMSAP1 | c.4088C>G p.S1363* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- CFAP74 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- CMPK2 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DACH2 | c.1717A>C p.N573H | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- EOMES | c.1768C>A p.P590T | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.213); called by muse, mutect2
- EPB41 | c.2026G>T p.E676* (on ENST00000343067 / NM_001166005.2; = p.E434* on NM_004437.4) | Nonsense Mutation (SNP) | VAF 59/140 reads (42%) | called by muse, mutect2, varscan2
- GP6 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.243); called by muse, mutect2
- GRIA3 | c.1802A>C p.N601T | Missense Mutation (SNP) | VAF 149/155 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIF4B | c.3078dup p.P1027Tfs*5 | Frame Shift Ins (INS) | VAF 32/111 reads (29%) | called by mutect2, pindel, varscan2
- KMT2B | c.4739A>G p.Q1580R | Missense Mutation (SNP) | VAF 199/317 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- LGALS9 | c.1022G>C p.R341T (on ENST00000395473 / NM_009587.3; = p.R309T on NM_002308.4) | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRP2 | c.12199T>A p.Y4067N | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- MATN2 | c.2759A>G p.N920S | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NUPR2 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- OR10G8 | c.930C>A p.S310R | Missense Mutation (SNP) | VAF 190/639 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4D11 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PARP6 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- RASEF | c.1849G>T p.V617F | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROBO3 | c.3286T>A p.C1096S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- RP1 | c.3235C>A p.Q1079K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.455); called by muse, varscan2
- SARDH | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SCPEP1 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- SEC16A | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2
- SLCO1B3 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- STRBP | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- SYT4 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOX3 | c.608C>G p.P203R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSEN15 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- UGGT2 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- VCPKMT | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XIRP2 | c.4931T>C p.V1644A (on ENST00000628543; = p.V1819A on NM_152381.6) | Missense Mutation (SNP) | VAF 101/272 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- AL031777.2 | c.141C>A p.G47= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as rs370218182; called by muse, mutect2, varscan2
- B3GNT7 | c.751C>T p.L251= | Silent (SNP) | VAF 81/168 reads (48%) | catalogued as rs1384019828; called by muse, mutect2, varscan2
- BCHE | c.987C>T p.D329= | Silent (SNP) | VAF 69/269 reads (26%) | catalogued as rs766000843; called by muse, mutect2, varscan2
- CARM1 | c.498C>T p.Y166= | Silent (SNP) | VAF 36/168 reads (21%) | catalogued as rs774776177, COSV100499146; called by muse, mutect2, varscan2
- CHST12 | c.888C>G p.L296= | Silent (SNP) | VAF 58/189 reads (31%) | called by muse, mutect2, varscan2
- CLEC3A | c.600C>T p.C200= (on ENST00000651443; = p.C191= on NM_005752.6) | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as rs757869038, COSV55219825; called by muse, mutect2, varscan2
- DUSP2 | c.343C>T p.L115= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs542663886; called by muse, mutect2, varscan2
- DYDC2 | c.174G>A p.Q58= | Silent (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- EXOSC6 | c.573C>T p.P191= | Silent (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- GJA8 | c.1164G>A p.S388= | Silent (SNP) | VAF 64/126 reads (51%) | catalogued as rs377042749, COSV99569424; called by muse, mutect2, varscan2
- IGLL5 | c.78G>C p.L26= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV73250938; called by muse, mutect2, varscan2
- KCNN2 | c.39G>C p.P13= (on ENST00000264773; = p.P225= on NM_021614.4) | Silent (SNP) | VAF 53/162 reads (33%) | catalogued as COSV53295087; called by muse, mutect2, varscan2
- KCNS1 | c.585C>T p.G195= | Silent (SNP) | VAF 41/75 reads (55%) | called by muse, mutect2, varscan2
- MAGEA10 | c.684A>T p.I228= | Silent (SNP) | VAF 48/133 reads (36%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.88T>C p.L30= | Silent (SNP) | VAF 46/121 reads (38%) | called by muse, mutect2, varscan2
- RANBP2 | c.8385A>G p.E2795= | Silent (SNP) | VAF 58/133 reads (44%) | catalogued as rs774055387; ClinVar: likely benign; called by muse, mutect2, varscan2
- RHCG | c.972G>A p.L324= | Silent (SNP) | VAF 95/289 reads (33%) | called by muse, mutect2, varscan2
- RNASEH2C | c.129G>A p.P43= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs774676282, COSV100383832; called by muse, mutect2, varscan2
- SLCO2B1 | c.1545C>T p.P515= | Silent (SNP) | VAF 50/175 reads (29%) | catalogued as rs1396577157, COSV99214408; called by muse, mutect2, varscan2
- TAPT1 | c.9C>T p.G3= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- TRIM71 | c.1947G>T p.R649= | Silent (SNP) | VAF 119/184 reads (65%) | called by muse, mutect2, varscan2
- ZNF718 | c.1314G>A p.L438= | Silent (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- AMOTL2 | c.*488C>T | 3'UTR (SNP) | VAF 47/160 reads (29%) | called by muse, mutect2, varscan2
- ARRDC3 | c.*315G>A | 3'UTR (SNP) | VAF 24/83 reads (29%) | called by muse, mutect2, varscan2
- B3GALNT1 | c.-44G>A | 5'UTR (SNP) | VAF 21/64 reads (33%) | catalogued as rs766026068; called by muse, mutect2, varscan2
- BBS4 | c.*97C>T | 3'UTR (SNP) | VAF 84/241 reads (35%) | called by muse, mutect2, varscan2
- BMP5 | c.*441A>T | 3'UTR (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- BST2 | c.-7G>A | 5'UTR (SNP) | VAF 88/398 reads (22%) | catalogued as rs1365074910; called by muse, mutect2, varscan2
- CBX4 | c.*695del | 3'UTR (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- CCDC186 | c.*2547T>C | 3'UTR (SNP) | VAF 82/190 reads (43%) | catalogued as rs1027206016; called by muse, mutect2, varscan2
- CELF5 | c.*40+14C>A | Intron (SNP) | VAF 41/190 reads (22%) | called by muse, mutect2, varscan2
- CEP170 | c.*1743C>T | 3'UTR (SNP) | VAF 56/116 reads (48%) | called by muse, mutect2, varscan2
- CLDN1 | c.*175T>C | 3'UTR (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- COA1 | c.-38-1184G>A | Intron (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- CTXN2 | chr15:48191563 G>A | 5'Flank (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- CXCL1 | c.*161_*164del | 3'UTR (DEL) | VAF 36/86 reads (42%) | called by mutect2, pindel, varscan2
- DDX53 | c.-68G>A | 5'UTR (SNP) | VAF 47/49 reads (96%) | called by muse, mutect2, varscan2
- EFCAB7 | c.947-2733C>G | Intron (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- FAM229B | c.*1714A>G | 3'UTR (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- FLRT3 | c.*479A>T | 3'UTR (SNP) | VAF 27/35 reads (77%) | called by muse, mutect2, varscan2
- FNIP1 | c.*2970G>C | 3'UTR (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137035367 G>A | 5'Flank (SNP) | VAF 41/140 reads (29%) | catalogued as rs1178630193; called by muse, mutect2, varscan2
- GADL1 | c.1250+2410C>G | Intron (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- GET4 | c.156-1255G>T | Intron (SNP) | VAF 34/94 reads (36%) | called by muse, mutect2, varscan2
- H4C9 | c.*146C>T | 3'UTR (SNP) | VAF 11/34 reads (32%) | catalogued as rs1458825172, COSV104416474; called by muse, mutect2, varscan2
- HACD2 | c.682+1190A>G | Intron (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- HTR2C | c.*2388T>C | 3'UTR (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- IGLL5 | c.-40C>T | 5'UTR (SNP) | VAF 33/62 reads (53%) | catalogued as rs145696836, COSV73251009; called by muse, mutect2, varscan2
- KBTBD12 | c.*2627C>T | 3'UTR (SNP) | VAF 29/102 reads (28%) | catalogued as rs978088669; called by muse, mutect2, varscan2
- LIFR | c.*812del | 3'UTR (DEL) | VAF 45/195 reads (23%) | called by mutect2, pindel, varscan2
- MACROH2A2 | c.*526G>A | 3'UTR (SNP) | VAF 22/54 reads (41%) | catalogued as rs11554214; called by muse, mutect2, varscan2
- MAGI1 | c.2168-199C>T | Intron (SNP) | VAF 49/135 reads (36%) | called by muse, mutect2, varscan2
- MAP2K6 | c.17-156C>G | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- MAPKAP1 | c.959-15317G>A | Intron (SNP) | VAF 24/772 reads (3%) | called by muse, mutect2
- MC2R | c.*193C>A | 3'UTR (SNP) | VAF 3/36 reads (8%) | catalogued as rs1037532009; called by muse, mutect2
- MCM10 | chr10:13211047 G>A | 3'Flank (SNP) | VAF 49/91 reads (54%) | called by muse, mutect2, varscan2
- MIR513C | n.78T>C | RNA (SNP) | VAF 108/114 reads (95%) | called by muse, mutect2, varscan2
- MTNR1B | c.223+2583A>T | Intron (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- NAA60 | c.-52G>T | 5'UTR (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- NECAB1 | c.*2834T>C | 3'UTR (SNP) | VAF 40/85 reads (47%) | called by muse, mutect2, varscan2
- NOL8 | c.*93_*94del | 3'UTR (DEL) | VAF 59/197 reads (30%) | called by mutect2, pindel, varscan2
- NUCKS1 | c.*2253G>A | 3'UTR (SNP) | VAF 46/99 reads (46%) | catalogued as rs1446730545; called by muse, mutect2, varscan2
- OGN | c.*866T>A | 3'UTR (SNP) | VAF 41/111 reads (37%) | called by muse, mutect2, varscan2
- PADI2 | c.*479T>A | 3'UTR (SNP) | VAF 46/106 reads (43%) | catalogued as rs1325729765; called by muse, mutect2, varscan2
- PDSS2 | c.*1431C>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | catalogued as rs1296150890; called by muse, mutect2
- PLK2 | c.-114G>A | 5'UTR (SNP) | VAF 17/70 reads (24%) | catalogued as rs918723338; called by muse, mutect2, varscan2
- PRKCB | c.1864-169C>T | Intron (SNP) | VAF 57/122 reads (47%) | called by muse, mutect2, varscan2
- RGL1 | c.*634C>T | 3'UTR (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- RPS27L | c.7-135T>C | Intron (SNP) | VAF 45/149 reads (30%) | called by muse, mutect2, varscan2
- RSPH6A | c.651-85A>T | Intron (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- SDCBP2 | c.225+11G>A | Intron (SNP) | VAF 46/61 reads (75%) | called by muse, mutect2, varscan2
- SESN3 | c.-156C>G | 5'UTR (SNP) | VAF 15/24 reads (63%) | catalogued as rs1430862061; called by muse, varscan2
- SGCE | c.1486+533A>T | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- SLC24A5 | c.301+976T>A | Intron (SNP) | VAF 39/110 reads (35%) | called by muse, mutect2, varscan2
- SLC28A1 | c.461+635_461+636insA | Intron (INS) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- SPINK5 | c.474+407G>A | Intron (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- STK4 | c.*54G>A | 3'UTR (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- TMEM132D | c.1444-1269G>A | Intron (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- TMEM196 | c.*936C>T | 3'UTR (SNP) | VAF 41/129 reads (32%) | called by muse, mutect2, varscan2
- TMEM69 | c.*143G>A | 3'UTR (SNP) | VAF 18/35 reads (51%) | catalogued as rs1426378733; called by muse, mutect2, varscan2
- TNRC18P2 | n.1100A>T | RNA (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- TRPV3 | c.*992C>T | 3'UTR (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- WDR55 | c.*2599G>T | 3'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- ZNF280D | c.381+905T>C | Intron (SNP) | VAF 37/112 reads (33%) | called by muse, mutect2, varscan2
- ZNF608 | c.*231T>A | 3'UTR (SNP) | VAF 20/52 reads (38%) | catalogued as rs891348476; called by muse, mutect2, varscan2
